TCGA case TCGA-DX-A3LW — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2cacd9d0-8414-4f17-8259-c9d838597f39

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 43 years; Vital status: Alive.

Diagnoses (3)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 43.7 years (15,969 days); Year of diagnosis: 2004; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 13; Tumor width measurement: 12.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 15; Tumor length measurement: 17; Tumor width measurement: 15.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Tumor depth descriptor: Deep.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 46.8 years (17,094 days); Days to diagnosis: 1,125 days (3.1 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 8.9; Tumor length measurement: 23.5; Tumor width measurement: 16.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 53.5 years (19,559 days); Days to diagnosis: 3,590 days (9.8 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 22.4.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 1,125 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 1,125 days (3.1 years).
- Days to follow up: 3,289 days (9.0 years); Disease response: Tumor Free.
- Day 3,590 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 3,590 days (9.8 years).
- Days to follow up: 3,794 days (10.4 years); Disease response: With Tumor.
- Days to follow up: 4,150 days (11.4 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A3LW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 540 mg.
  Slide TCGA-DX-A3LW-01A-02-TS2: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 1; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-DX-A3LW-01A-01-TS1: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 1; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A3LW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A3LW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Margin status: Positive; Disease multifocal indicator: No; Well diff liposarc prior diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,150 days; disease-specific survival: no event (censored), 4,150 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,125 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A3LW-01A-21D-A21P-01): tumor purity 0.9, ploidy 1.99, whole-genome doublings 0.
